Surgical pathology report (de-identified scan), TCGA case TCGA-CX-7086, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Medical College of Georgia, specimen TCGA-CX-7086-01A (Primary Tumor).

[page 1 of 11]
TCGA 8005

F i n a l P a t h o l o g y D i a g n o s i s R e p o r t

Accession Number: Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

Final Pathologic Diagnosis

CORRECTED REPORT

A) RIGHT DISTAL MENTAL NERVE (BIOPSY):

- Negative for carcinoma.

B) LEFT DISTAL MENTAL NERVE (BIOPSY):

- Negative for carcinoma.

C) ANTERIOR MENTAL MARGIN (BIOPSY):

- Negative for carcinoma.

D) COMPOSITE RESECTION FLOOR OF MOUTH (BIOPSY):

- Invasive squamous cell carcinoma, moderately differentiated, keratinizing type.

E) RIGHT LATERAL MANDIBLE MARGIN (BIOPSY):

- Negative for carcinoma.

F) COMPOSITE RESECTION FLOOR OF MOUTH (MANDIBULECTOMY):

- Invasive squamous cell carcinoma, moderately differentiated, keratinizing type (see synoptic report).
- Metastatic carcinoma involving one of eight lymph nodes (1/8).

G) SUPER HYOID MUSCLE MARGIN (BIOPSY):

- Negative for carcinoma.

H) ANTERIOR VENTRICLE TONGUE MARGIN (BIOPSY):

- Negative for carcinoma.

[page 2 of 11]
Patient Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED] Sex: Male [REDACTED]
Account Number: [REDACTED]
Visit Date: [REDACTED]
Discharge date: [REDACTED]
Patient Type: [REDACTED]
Location: [REDACTED]
Attending Physician: [REDACTED]

F i n a l P a t h o l o g y D i a g n o s i s R e p o r t

Accession Number: [REDACTED] Senior Pathologist: [REDACTED]

Collected Date/Time: [REDACTED]
Received Date/Time: [REDACTED]
Verified Date/Time: [REDACTED]

I) LEFT LATERAL VENTRAL TONGUE MARGIN (BIOPSY):

- Negative for carcinoma.

J) RIGHT LATERAL VENTRAL TONGUE MARGIN (BIOPSY):

- Negative for carcinoma.

K) RIGHT POSTERIOR FLOOR OF MOUTH MARGIN (BIOPSY):

- Negative for carcinoma.

L) LEFT POSTERIOR FLOOR OF MOUTH MARGIN (BIOPSY):

- Negative for carcinoma.

M) ANTERIOR DEEP VENTRAL TONGUE MARGIN (BIOPSY):

- Negative for carcinoma.

N) MIDDLE DEEP VENTRAL TONGUE MARGIN (BIOPSY):

- Negative for carcinoma.

O) POSTERIOR DEEP VENTRAL TONGUE MARGIN (BIOPSY):

- Negative for carcinoma.

P) RIGHT POSTERIOR LINGUAL GINGIVAL MARGIN (BIOPSY):

- Negative for carcinoma.

Q) LEFT POSTERIOR LINGUAL GINGIVAL MARGIN (BIOPSY):

- Negative for carcinoma.

R) LEFT POSTERIOR BUCCAL GINGIVAL MARGIN (BIOPSY):

- Negative for carcinoma.

S) RIGHT POSTERIOR BUCCAL GINGIVAL MARGIN (BIOPSY):

- Negative for carcinoma.

[page 3 of 11]
F i n a l P a t h o l o g y D i a g n o s i s R e p o r t

Accession Number: Senior Pathologist:

Collected Date/Time:
Received Date/Time:
Verified Date/Time:

T) RIGHT SUBMANDIBULAR GLAND (BIOPSY):

- Benign mixed salivary gland.
- Negative for malignancy.

U) RIGHT LEVEL 4 (NECK DISSECTION):

- Fourteen benign lymph nodes (0/14).
- Negative for malignancy.

V) RIGHT LEVEL 3 (NECK DISSECTION):

- Seven benign lymph nodes (0/7).
- Negative for malignancy.

W) RIGHT LEVEL 2 (NECK DISSECTION):

- Ten benign lymph nodes (0/10).
- Negative for malignancy.

X) LEFT LEVEL 2 (BIOPSY):

- Seven benign lymph nodes (0/7).
- Negative for malignancy.

Y) LEFT LEVEL 3 (NECK DISSECTION):

- Three benign lymph nodes (0/3).
- Negative for malignancy.

Z) LEFT LEVEL 4 (NECK DISSECTION):

- Fifteen benign lymph nodes (0/15).
- Negative for malignancy.

NOTE: This corrected report is being issued to correctly identify the attending pathologist responsible for reading

[page 4 of 11]
F i n a l P a t h o l o g y D i a g n o s i s R e p o r t

Accession Number:

Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

each frozen section diagnosis. The initial diagnosis rendered by remains unchanged.

I attest I have personally reviewed the specimen/slides and agree with the above findings.

Resident:

Synoptic Report

F: Lip and Oral Cavity -

SPECIMEN (Select all that apply):

Ventral surface of tongue, not otherwise specified (NOS)

Lower gingiva (gum)

Anterior floor of mouth

Mandible

RECEIVED:

Fresh

PROCEDURE (Select all that apply):

Resection

Mandibulectomy (specify): Partial

Neck (lymph node) dissection (specify): Bilateral Radical

SPECIMEN INTEGRITY:

Intact

SPECIMEN SIZE:

Greatest dimensions: 11.5 cm

Additional dimensions (if more than one part): 10.0 x 6.0 cm

SPECIMEN LATERALITY:

Midline

TUMOR SITE (Select all that apply):

Ventral surface of tongue, not otherwise specified (NOS)

Lower gingiva (gum)

Anterior floor of mouth

TUMOR FOCALITY:

[page 5 of 11]
F i n a l P a t h o l o g y D i a g n o s i s R e p o r t

Accession Number: Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

Single focus

TUMOR SIZE:

Greatest dimensions: 5.0 cm

Additional dimensions: 3.3 x 1.7 cm

TUMOR THICKNESS (pT1 AND pT2 Tumors):

Tumor thickness: 17 mm

TUMOR DESCRIPTION (Select all that apply):

Gross subtype

Exophytic

MACROSCOPIC EXTENT OF TUMOR:

Specify: Exophytic mass identified at the floor of mouth (5.0 x 3.3 x 1.0 cm) which extends from the ventral aspect of the tongue to the anterior surface of the gums.

HISTOLOGIC TYPE (Select all that apply):

Squamous cell carcinoma, conventional

HISTOLOGIC GRADE:

G2: Moderately differentiated

MARGINS (Select all that apply):

Margins uninvolved by invasive carcinoma

Distance from closest margin: 2 to 3 mm

Specify margin(s), per orientation, if possible: Blue - right posterior lateral soft tissue resection margin; Green - left posterior soft tissue resection margin;

TREATMENT EFFECT:

Not identified

LYMPH-VASCULAR INVASION:

Present

PERINEURAL INVASION:

Not identified

LYMPH NODES, EXTRANODAL EXTENSION:

Present

PATHOLOGIC STAGING (pTNM):

TNM Descriptors (select all that apply)

PRIMARY TUMOR (pT)

pT3: Tumor more than 4 cm in greatest dimension

REGIONAL LYMPH NODES (pN)

pN1: Metastasis in a single ipsilateral lymph node, 3 cm or less in greatest dimension

Specify: Number examined: 64

Number involved: 1

DISTANT METASTASIS

Not Applicable

[page 6 of 11]
F i n a l P a t h o l o g y D i a g n o s i s R e p o r t

Accession Number: Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

ADDITIONAL PATHOLOGIC FINDINGS (Select all that apply):

None identified

Intraoperative Diagnosis

FS A1: Negative for tumor.

FS B1: Negative for tumor.

FS C1: Negative for tumor.

FS E1: Negative for malignancy.

FS G1: Negative for malignancy.

FS H1: Negative.

FS I1: Negative.

FS J1: Negative.

FS K1: Negative.

FS L1: Negative.

FS M1: Negative.

FS N1: Negative.

FS O1: Negative.

FS P1: Negative.

FS Q1: Negative.

FS R1: Negative.

FS S1: Negative.

Clinical History

Not provided.

Pre/Post-operative Diagnosis

Squamous cell carcinoma mandible.

Gross Anatomic Description

(Dictated by

[page 7 of 11]
F i n a l P a t h o l o g y D i a g n o s i s R e p o r t

Accession Number: Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

Specimens received in twenty-six containers.

Specimen A: Designated "right distal mental nerve" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "right distal mental nerve". Specimen consists of a single piece of red/tan, soft tissue measuring 0.5 x 0.4 x 0.4 cm. The entire specimen is submitted for frozen section.

Section code: A1 – frozen section control.

Specimen B: Designated "left distal mental nerve" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "left distal mental nerve". Specimen consists of a single piece of tan/red, soft tissue measuring 0.4 x 0.4 x 0.3 cm. The entire specimen is submitted for frozen section.

Section code: B1 – frozen section control.

Specimen C: Designated "anterior mental margin" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "anterior mental margin". Specimen consists of three pieces of red, soft tissue measuring 0.3 x 0.3 x 0.3 cm in aggregate. The entire specimen is submitted for frozen section.

Section code: C1 – frozen section control.

Specimen D: Designated "composite resection floor of mouth" is received fresh for Tumor Bank on [REDACTED] labeled with the patient's name and "composite resection floor of mouth". Specimen consists of a single piece of tan, soft tissue measuring 1.8 x 1.2 x 0.7 cm. A representative portion is submitted to Tumor Bank.

Section code: D1 – remainder of specimen.

Specimen E: Designated "right lateral mandible margin" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "right lateral mandible margin". Specimen consists of a single piece of bone and marrow measuring 2.0 x 1.2 x 0.3 cm. The bone marrow portion is submitted for frozen section.

Section code: E1 – frozen section control; E2 – remainder of specimen after decalcification.

Specimen F: Designated "composite resection floor of mouth" is received fresh for Tumor Bank on [REDACTED] labeled with the patient's name and "composite resection floor of mouth". Specimen consists of one mandibulectomy specimen measuring 11.5 x 10.0 x 6.0 cm and weighing 179.8 g in total. The portion of mandible measures 11.0 cm in length, 3.0 cm in height and 1.7 cm in thickness. Eleven teeth are identified intact. One detached tooth is identified. There is a light tan, fungating, exophytic mass identified at the floor of mouth which measures 5.0 x 3.3 x 1.0 cm and extends from the ventral aspect of the tongue to the anterior surface of the gums. The mass comes within 0.2 cm of the closest posterior mucosal resection margins located at the left and right lateral-posterior aspect. Cut surface of the mandible at midline reveals an area suspicious for invasion measuring 0.5 cm. Multiple lymph nodes are identified, primarily at the inferior aspect of the specimen. Gross photographs are taken.

Inking code: Red – right mandible resection margin; Yellow – left mandible resection margin; Blue – right posterior soft tissue resection margin; Green – left posterior soft tissue resection margin; Orange – right anterior soft tissue resection margin; Black – left anterior soft tissue resection margin.

[page 8 of 11]
F i n a l P a t h o l o g y D i a g n o s i s R e p o r t

Accession Number: Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

Section code: F1 – tumor with closest mucosal resection margin, left posterior lateral; F2 – tumor with closest mucosal resection margin, right posterior lateral; F3 – anterior portion of tumor with gums and resection margin including one tooth, after decalcification; F4 – posterior ventral tongue resection margin; F5 – right mandible resection margin, en face, after decalcification; F6 – left mandible resection margin, en face, after decalcification; F7-F8 – representative section including full thickness anterior medial portion of mandible with possible tumor invasion invading bone (after decalcification for F7), bisected; F9 – three suspected lymph nodes, wholly submitted; F10-F11 – one suspected lymph node with suspected metastasis, bisected; F12 – one suspected lymph node, bisected; F13 – one suspected lymph node, bisected; F14-F15 – one suspected lymph node, bisected; F16 – one suspected lymph node, bisected; F17 – posterior ventral tongue; F18-F19 – additional representative full thickness sections; F20-F21 – additional right mandible resection margin, en face.

Specimen G: Designated "suprahyoid muscle margin" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "suprahyoid muscle margin". Specimen consists of multiple pieces of red, soft tissue measuring 1.6 x 1.0 x 0.4 cm in aggregate. The specimen is submitted entirely for frozen section. Section code: G1 – frozen section control.

Specimen H: Designated "anterior ventral tongue margin" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "anterior ventral tongue margin". Specimen consists of three pieces of red, soft tissue measuring 0.8 x 0.5 x 0.3 cm in aggregate. The specimen is submitted entirely for frozen section. Section code: H1 – frozen section control.

Specimen I: Designated "left lateral ventral tongue margin" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "left lateral ventral tongue margin". Specimen consists of one piece of pink/tan, soft tissue measuring 4.3 x 0.2 x 0.2 cm. The entire specimen is submitted for frozen section. Section code: I1 – frozen section control.

Specimen J: Designated "right lateral ventral tongue margin" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "right lateral ventral tongue margin". Specimen consists of two pieces of pink/tan, soft tissue measuring 1.6 x 0.7 x 0.2 cm. The specimen is submitted entirely for frozen section. Section code: J1 – frozen section control.

Specimen K: Designated "right posterior floor of mouth margin" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "right posterior floor of mouth margin". Specimen consists of one piece of pink/tan, soft tissue measuring 2.5 x 0.3 x 0.2 cm. The entire specimen is submitted for frozen section. Section code: K1 – frozen section control.

Specimen L: Designated "left posterior floor of mouth margin" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "left posterior floor of mouth margin". Specimen consists of one piece of pink/tan, soft tissue measuring 2.0 x 0.3 x 0.2 cm. The entire specimen is submitted for frozen section. Section code: L1 – frozen section control.

[page 9 of 11]
F i n a l P a t h o l o g y D i a g n o s i s R e p o r t

Accession Number: Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

Specimen M: Designated "anterior deep ventral tongue margin" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "anterior deep ventral tongue margin". Specimen consists of two pieces of pink/tan, soft tissue measuring 1.0 x 0.4 x 0.2 cm in aggregate. The specimen is submitted entirely for frozen section.

Section code: M1 – frozen section control.

Specimen N: Designated "middle deep ventral tongue margin" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "middle deep ventral tongue margin". Specimen consists of one piece of pink/tan, soft tissue measuring 1.4 x 0.4 x 0.2 cm. The entire specimen is submitted for frozen section.

Section code: N1 – frozen section control.

Specimen O: Designated "posterior deep ventral tongue margin" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "posterior deep ventral tongue margin". Specimen consists of one piece of red, soft tissue measuring 0.9 x 0.5 x 0.3 cm. The entire specimen is submitted for frozen section.

Section code: O1 – frozen section control.

Specimen P: Designated "right posterior lingual gingival margin" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "right posterior lingual gingival margin". Specimen consists of one piece of red, soft tissue measuring 1.5 x 0.2 x 0.2 cm. The entire specimen is submitted for frozen section.

Section code: P1 – frozen section control.

Specimen Q: Designated "left posterior lingual gingival margin" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "left posterior lingual gingival margin". Specimen consists of one piece of pink, soft tissue measuring 1.0 x 0.3 x 0.1 cm. The entire specimen is submitted for frozen section.

Section code: Q1 – frozen section control.

Specimen R: Designated "left posterior buccal gingival margin" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "left posterior buccal gingival margin". Specimen consists of one piece of red, soft tissue measuring 0.6 x 0.6 x 0.3 cm. The entire specimen is submitted for frozen section.

Section code: R1 – frozen section control.

Specimen S: Designated "right posterior buccal gingival margin" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "right posterior buccal gingival margin". Specimen consists of two pieces of red, soft tissue measuring 0.6 x 0.5 x 0.2 cm in aggregate. The specimen is submitted entirely for frozen section.

Section code: S1 – frozen section control.

[page 10 of 11]
F i n a l P a t h o l o g y D i a g n o s i s R e p o r t

Accession Number: Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

Specimen T: Designated "right submandibular gland" is received in formalin labeled with the patient's name and "right submandibular gland". Specimen consists of a single, pink/tan, lobulated and smooth fragment of soft tissue measuring 5.2 x 3.5 x 2.0 cm and weighing 12.7 g. Cut surface is pink/tan with a lobulated appearance. No distinct lesions or masses are identified.

Inking code: Green – external surface.

Section code: T1-T3 – representative sections.

Specimen U: Designated "right level 4" is received in formalin labeled with the patient's name and "right level 4". Specimen consists of a single pink/tan fragment of soft tissue measuring 7.7 x 2.5 x 1.7 cm.

Section code: U1 – seven suspected lymph nodes, submitted wholly; U2 – representative section; U3 – four suspected lymph nodes, submitted wholly; U4 – representative section.

Specimen V: Designated "right level 3" is received in formalin labeled with the patient's name and "right level 3". Specimen consists of multiple pink/tan fragments of soft tissue measuring 4.7 x 4.5 x 2.0 cm in aggregate. Multiple lymph nodes are palpated.

Section code: V1-V2 – multiple suspected lymph nodes; V3-V5 – remainder of specimen.

Specimen W: Designated "right level 2" is received in formalin labeled with the patient's name and "right level 2". Specimen consists of a single pink/tan fragment of soft tissue measuring 4.3 x 2.7 x 1.3 cm. Multiple lymph nodes are identified.

Section code: W1 – multiple suspected lymph nodes; W2-W3 – representative sections; W4-W5 – one suspected lymph node, bisected.

Specimen X: Designated "left level 2" is received in formalin labeled with the patient's name and "left level 2". Specimen consists of a single fragment of pink/tan soft tissue measuring 5.3 x 2.6 x 1.3 cm.

Section code: X1-X3 – representative sections; X4-X5 – one suspected lymph node, bisected.

Specimen Y: Designated "left level 3" is received in formalin labeled with the patient's name and "left level 3". Specimen consists of a single fragment of pink/tan soft tissue measuring 4.8 x 2.8 x 1.7 cm. Multiple lymph nodes are palpated.

Section code: Y1 – one suspected lymph node, bisected; Y2 – one suspected lymph node; Y3-Y5 – remainder of specimen.

Specimen Z: Designated "left level 4" is received in formalin labeled with the patient's name and "left level 4". Specimen consists of a single fragment of pink/tan soft tissue measuring 4.5 x 3.5 x 1.5 cm. Multiple lymph nodes are identified.

Section code: Z1-Z2 – multiple suspected lymph nodes; Z3-Z5 – remainder of specimen.

[page 11 of 11]
I n t r a o p e r a t i v e D i a g n o s i s R e p o r t

Accession Number: Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

Intraoperative Diagnosis

FS A1: Negative for tumor.

FS B1: Negative for tumor.

FS C1: Negative for tumor.

FS E1: Negative for malignancy.

FS G1: Negative for malignancy.

FS H1: Negative.

FS I1: Negative.

FS J1: Negative.

FS K1: Negative.

FS L1: Negative.

FS M1: Negative.

FS N1: Negative.

FS O1: Negative.

FS P1: Negative.

FS Q1: Negative.

FS R1: Negative.

FS S1: Negative.

Source: NCI Genomic Data Commons file a0ec36fc-f485-4600-800f-13740085a499 (TCGA-CX-7086.AC00D39F-2F9E-4EEA-B174-BA95D2451607.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).